Somatic mutation profile of tumor specimen TCGA-FR-A8YD-06A (aliquot TCGA-FR-A8YD-06A-11D-A372-08) from TCGA case TCGA-FR-A8YD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.0 years (21,535 days).
Specimen TCGA-FR-A8YD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae3f58c3-1b43-4124-aaa0-6242ee3896d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A8YD-10A (Blood Derived Normal), aliquot TCGA-FR-A8YD-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb90aad2-4ed1-454b-aad1-6dc725dbceb9

The open-access MAF lists 115 somatic variants for this specimen: 96 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 17, Splice Site 7, Nonsense Mutation 3, Frame Shift Ins 2, 5'Flank 1, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3445A>G p.M1149V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1187097568, CM143377, COSV100646550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1393G>C p.A465P | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV101036770; called by muse, mutect2, varscan2
- AFF2 | c.3583A>G p.K1195E | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99663027; called by muse, mutect2, varscan2
- AGBL1 | c.2066G>A p.C689Y | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs757373166, COSV101222594; called by muse, mutect2, varscan2
- ATP5F1A | c.1200C>G p.F400L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV99958832; called by muse, mutect2
- ATXN1 | c.2159G>T p.R720I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV55220984, COSV99785884; called by muse, mutect2, varscan2
- BABAM2 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 74/181 reads (41%) | catalogued as COSV100567628; called by muse, mutect2, varscan2
- BCAT2 | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100302367; called by muse, mutect2, varscan2
- BCORL1 | c.3614T>C p.L1205S | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99499015; called by muse, mutect2, varscan2
- BHMT2 | c.339C>G p.I113M | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV99670028; called by muse, mutect2, varscan2
- BMP2K | c.2274G>C p.E758D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.065); catalogued as COSV99784994; called by muse, mutect2, varscan2
- BOC | c.3293C>T p.S1098F | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV99848460; called by muse, mutect2, varscan2
- CASP5 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV52829633; called by muse, mutect2, varscan2
- CBX5 | c.572G>T p.S191I | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV99267513; called by muse, mutect2
- CCAR1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV99770868; called by muse, mutect2, varscan2
- CCPG1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as rs1231488623, COSV100197049; called by muse, mutect2, varscan2
- CD300C | c.168G>C p.W56C | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478582619, COSV100423230, COSV58170080; called by muse, mutect2
- CD300E | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV60792360; called by muse, mutect2, varscan2
- CD69 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99946034; called by muse, mutect2, varscan2
- CEACAM20 | c.290T>A p.I97N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100386831; called by muse, varscan2
- CERK | c.929G>T p.R310I | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99348516; called by muse, mutect2
- CHD8 | c.2575C>T p.H859Y (on ENST00000646647 / NM_001170629.2; = p.H580Y on NM_020920.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV101303085; called by muse, mutect2, varscan2
- CLEC5A | c.453-1G>T p.X151_splice | Splice Site (SNP) | VAF 20/152 reads (13%) | catalogued as rs1328082886, COSV101407755; called by muse, mutect2, varscan2
- CLK4 | c.1409T>G p.L470W | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100308876; called by muse, mutect2, varscan2
- COL11A2 | c.4465G>A p.G1489S (on ENST00000341947 / NM_080680.3; = p.G1382S on NM_080679.2) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1411321, COSV100553720; called by muse, mutect2, varscan2
- EGFL6 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100789865; called by muse, mutect2, varscan2
- ERBB3 | c.136T>G p.Y46D | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV99916410; called by muse, mutect2, varscan2
- FLNA | c.4411T>A p.F1471I | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100774476; called by muse, mutect2
- FUT3 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771268621, COSV54604935; called by muse, mutect2, varscan2
- GCNT1 | c.285C>G p.N95K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV100946500; called by muse, mutect2, varscan2
- HCFC1 | c.2927A>G p.D976G | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV100128743; called by muse, mutect2, varscan2
- HEATR4 | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV100620279; called by muse, mutect2
- HOXA7 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636332; called by muse, mutect2, varscan2
- HYKK | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100856433; called by muse, mutect2, varscan2
- IL2RB | c.903+1G>C p.X301_splice | Splice Site (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99344833; called by muse, mutect2
- KAT6B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54751414; called by muse, mutect2, varscan2
- KATNIP | c.1391A>G p.D464G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.242); catalogued as COSV99850592; called by muse, mutect2, varscan2
- KCNG4 | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100376970; called by muse, mutect2, varscan2
- KDM6A | c.2217C>G p.N739K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV100938043; called by muse, mutect2, varscan2
- KIAA0930 | c.905T>C p.F302S (on ENST00000336156 / NM_001009880.2; = p.F307S on NM_015264.2) | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as rs1165908713, COSV99325722; called by muse, mutect2, varscan2
- KLRC2 | c.585-1G>T p.X195_splice | Splice Site (SNP) | VAF 42/100 reads (42%) | catalogued as COSV101122662; called by muse, mutect2, varscan2
- KPNA4 | c.204G>A p.V68= | Splice Region (SNP) | VAF 65/125 reads (52%) | catalogued as COSV100515111; called by muse, mutect2, varscan2
- LAMP2 | c.422T>G p.L141W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.799); catalogued as COSV99568374; called by muse, mutect2, varscan2
- MAP7D2 | c.1568G>C p.R523P | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101107277, COSV65530773, COSV65530919; called by muse, mutect2, varscan2
- MCAM | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs374860225; called by muse, mutect2, varscan2
- MUC17 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV100072581; called by muse, mutect2, varscan2
- MYH1 | c.4396G>C p.E1466Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV99875436; called by muse, mutect2, varscan2
- MYL6B | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99255125; called by muse, mutect2, varscan2
- NBN | c.1010C>A p.T337N | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV55372251, COSV55377497; called by muse, mutect2, varscan2
- NCOA6 | c.2196C>G p.N732K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.366); catalogued as COSV100749947; called by muse, mutect2
- NF1 | c.3326T>G p.L1109* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as CM1312708, COSV100646548; called by muse, varscan2
- NFAT5 | c.4589C>T p.S1530F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV63029202; called by muse, mutect2, varscan2
- NLGN4X | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as COSV52004189, COSV99320988; called by muse, mutect2, varscan2
- NOL6 | c.2226G>C p.E742D | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99954632; called by muse, mutect2, varscan2
- NUDCD1 | c.459+2T>C p.X153_splice | Splice Site (SNP) | VAF 26/192 reads (14%) | catalogued as COSV99516970; called by muse, mutect2, varscan2
- OR1C1 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV101376209; called by muse, mutect2, varscan2
- OR2K2 | c.742T>G p.F248V (on ENST00000374428; = p.F219V on NM_205859.2) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100235235; called by muse, mutect2, varscan2
- PCDHA8 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.644); catalogued as rs558861388, COSV100970582; called by muse, mutect2, varscan2
- PCDHGB6 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300122367, COSV99534899; called by muse, mutect2, varscan2
- PENK | c.656G>C p.R219P | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201807450, COSV100152256; called by muse, mutect2, varscan2
- PKHD1L1 | c.12208T>C p.S4070P | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV101005877; called by muse, mutect2, varscan2
- PKHD1L1 | c.12209C>A p.S4070Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV101005878; called by muse, mutect2, varscan2
- PLCB1 | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100570186; called by muse, mutect2, varscan2
- POF1B | c.854+2T>C p.X285_splice | Splice Site (SNP) | VAF 14/59 reads (24%) | catalogued as rs1190234387, COSV99426407; called by muse, mutect2, varscan2
- POU5F2 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs1296066030, COSV101232705; called by muse, mutect2, varscan2
- PPFIA4 | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs764018548, COSV99829779; called by muse, varscan2
- PTPRZ1 | c.6072G>T p.E2024D | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.493); catalogued as rs754717245, COSV101099889; called by muse, mutect2, varscan2
- QRICH2 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762004308, COSV99428981; called by muse, mutect2, varscan2
- RGMA | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.999); catalogued as rs1191351472, COSV100224294; called by muse, mutect2
- SEMA4B | c.2063G>A p.S688N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.363); catalogued as rs199948601, COSV100153265; called by muse, varscan2
- SHISA5 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99604500; called by muse, mutect2, varscan2
- SLC18A3 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339972; called by muse, mutect2, varscan2
- SLC37A1 | c.617T>G p.L206W | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100721629; called by muse, mutect2
- STX1A | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99736460; called by muse, mutect2, varscan2
- SZT2 | c.10139C>T p.S3380F (on ENST00000634258 / NM_001365999.1; = p.S3323F on NM_015284.4) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.97); catalogued as COSV100981253; called by muse, mutect2, varscan2
- TAX1BP1 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 123/184 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs1338874039, COSV99604329; called by muse, mutect2, varscan2
- TBC1D16 | c.1387T>G p.S463A | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100187904; called by muse, mutect2, varscan2
- TENM1 | c.7054G>A p.D2352N | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.367); catalogued as COSV100949607; called by muse, mutect2, varscan2
- TLN2 | c.6271G>T p.A2091S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100168599; called by muse, mutect2, varscan2
- TLN2 | c.6272C>T p.A2091V | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs748536008, COSV100168601; called by muse, mutect2, varscan2
- TNC | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs200404684, COSV100405431; called by muse, mutect2, varscan2
- TNXB | c.6605G>T p.G2202V (on ENST00000647633; = p.G1955V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100926138; called by muse, mutect2, varscan2
- TTC3 | c.3497A>T p.D1166V | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100695284; called by muse, mutect2, varscan2
- TTN | c.4208+1G>A p.X1403_splice (on ENST00000591111; = p.X1357_splice on NM_003319.4) | Splice Site (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100603585; called by muse, mutect2, varscan2
- TVP23A | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564537498, COSV99296711; called by muse, mutect2, varscan2
- USP8 | c.2883A>C p.K961N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV100208897; called by muse, mutect2, varscan2
- WDR27 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs370224643; called by muse, mutect2, varscan2
- ZBTB20 | c.2196C>A p.D732E (on ENST00000474710 / NM_001164342.2; = p.D659E on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.947); catalogued as COSV100613353; called by muse, mutect2, varscan2
- ZNF420 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs757606983, COSV100421248; called by muse, mutect2, varscan2
- ZNF549 | c.746G>C p.R249P (on ENST00000376233 / NM_001199295.2; = p.R236P on NM_153263.2) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs200419451, COSV99558447; called by muse, mutect2, varscan2
- ZNF790 | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100764799; called by muse, mutect2, varscan2
- FEM1C | c.115dup p.T39Nfs*17 | Frame Shift Ins (INS) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- FERMT2 | c.390del p.F130Lfs*12 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- RTKN | c.374-2_374-1insAA p.X125_splice (on ENST00000272430 / NM_001015055.2; = p.X112_splice on NM_033046.2) | Splice Site (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- ZNF416 | c.342_343insT p.D115* | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | called by mutect2, pindel*, varscan2
- AADAC | c.60T>C p.Y20= | Silent (SNP) | VAF 50/67 reads (75%) | catalogued as COSV99233167; called by muse, mutect2, varscan2
- ATXN1 | c.2160A>G p.R720= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99785883; called by muse, mutect2, varscan2
- BRWD3 | c.2418T>C p.N806= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100955876, COSV64749231; called by muse, mutect2, varscan2
- CNTNAP5 | c.246G>T p.L82= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1424341701, COSV101443305; called by muse, mutect2, varscan2
- HNRNPA1 | c.12A>C p.S4= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99267515; called by muse, mutect2, varscan2
- MAN1A2 | c.1587C>T p.I529= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs778406715, COSV62976659; called by muse, mutect2, varscan2
- ME1 | c.153G>A p.Q51= | Silent (SNP) | VAF 35/55 reads (64%) | catalogued as rs1285293616, COSV100866429; called by muse, mutect2, varscan2
- MTMR8 | c.1947C>A p.S649= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100878404; called by muse, mutect2, varscan2
- MYH1 | c.2088G>A p.Q696= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99875437; called by muse, mutect2, varscan2
- NEK6 | c.825C>A p.S275= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs140302963, COSV100206757; called by muse, mutect2, varscan2
- NEO1 | c.3081A>G p.P1027= | Silent (SNP) | VAF 62/94 reads (66%) | catalogued as rs760423968, COSV99981702; called by muse, mutect2, varscan2
- NMUR2 | c.1074A>G p.P358= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV99676767; called by muse, mutect2, varscan2
- OR8B12 | c.417G>A p.V139= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100172731; called by muse, mutect2, varscan2
- RPGRIP1 | c.180G>A p.V60= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52849877; called by muse, mutect2, varscan2
- SELE | c.1239C>T p.G413= | Silent (SNP) | VAF 44/258 reads (17%) | catalogued as rs781437104, COSV100324660, COSV60976925; called by muse, mutect2, varscan2
- STYXL2 | c.813G>A p.L271= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs1229012887, COSV99608910; called by muse, mutect2, varscan2
- ZNF451 | c.1827G>A p.R609= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV100674816; called by muse, mutect2, varscan2
- MIR206 | n.28T>A | RNA (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173865986 del A | 5'Flank (DEL) | VAF 19/120 reads (16%) | called by mutect2, pindel, varscan2
